Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A4MD, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A4MD-06A (Metastatic).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Lymph node, right neck level 2B, regional node dissection
- No tumor seen in two lymph nodes (0/2).

B: Lymph node, central compartment right neck, regional node dissection
- Metastatic papillary thyroid carcinoma in 1 of 2 lymph nodes (1/2); maximum size of metastasis 0.8 cm; negative for definite extracapsular extension.
- Normocellular parathyroid tissue identified.

C: Thyroid, left, lobectomy
- Papillary microcarcinoma, 0.16 cm, surgical resection margins negative

D: Thyroid, right, lobectomy

Tumor histologic type: papillary thyroid carcinoma

Tumor size: 6.0 cm maximum dimension in right superior/middle thyroid by gross examination

Tumor growth pattern: infiltrative

Tumor focality: unifocal

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid nos C73.9 1/14/12

Extent of invasion:

Lymphovascular: present

Blood vascular: not identified

Extra thyroidal extension: not identified

Surgical margins: negative but close; carcinoma <0.1 cm from the black inked posterior and blue inked anterior resection margins

Status of thyroid gland away from tumor: focal mild non-specific chronic inflammation

Lymph nodes: Metastatic carcinoma in 1 of 3 lymph nodes in this specimen (1/3), maximum size of metastasis 0.8 cm, negative for extracapsular extension in this specimen; Total lymph node count

[page 2 of 5]
for all specimens is metastatic papillary carcinoma in 9 of 41 lymph nodes (9/41); maximum size of metastasis 6.0 cm by gross examination (specimen E), focal extracapsular extension identified (specimen E).

AJCC PATHOLOGIC TNM STAGE: pT3 pN1b

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

E: Lymph node, right, modified neck dissection (2, 3, 4)
- Metastatic papillary carcinoma in 7 of 24 lymph nodes (7/24), maximum size of metastasis 6.0 cm by gross examination, focal extracapsular extension identified.

F: Lymph node, right neck level 2B, regional node dissection
- No tumor seen in ten lymph nodes (0/10).

Clinical History:

The patient is a -year-old man with history of thyroid carcinoma, clinical

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "right neck level 2B" is a 2.3 x 1.8 x 1.4 cm fragment of markedly cauterized yellow/tan fibrofatty tissue is dissected for lymph node candidates. Three lymph node candidates up to 1.1 cm in greatest dimension are identified.

Block Summary:

A1 - Three lymph node candidates
A small amount of tissue remains in formalin

Container B is additionally labeled "central compartment right neck" it holds a 1.7 x 1.7 x 0.6 cm aggregate of cauterized yellow/tan fibrofatty tissue containing three lymph node candidates up to 1.5 cm in greatest dimension.

Block Summary:

[page 3 of 5]
B1 - Two lymph node candidates
B2 - One lymph node candidate, sectioned,

Container C is additionally labeled "left thyroid lobe" is a 7.8 gram 5.3 x 2.8 x 1.2 cm lobe of thyroid. Specimen is received focally disrupted along the lateral portion of the specimen. Inked as follows, anterior blue, posterior black and isthmus yellow. Specimen is sectioned from superior toward inferior to reveal a dark red/brown homogenous parenchyma with no focal lesions noted.

Representative sections are submitted in blocks C1-C4.

Container D is additionally labeled "right thyroid lobe"

Specimen fixation: Formalin

Type of specimen: Lobectomy

Size and weight of specimen: 84.8 grams, 6.0 x 5.8 x 4.5 cm

Orientation: Anterior blue, posterior black and isthmus yellow

Tumor location: Right lobe, occupies the majority of the lobe

Focality: Unifocal

Dominant tumor: Present

Tumor description: A solid variegated tan/red to gray/brown friable mass

Tumor size: 5.5 cm right to left, 6 cm superior to inferior and 4.5 cm anterior to posterior

Confinement/non-confinement: The overlying soft tissue is markedly expanded but grossly appears intact.

Distance of tumor to surgical margins: Focally abuts blue inked anterior, black inked posterior margin and is within 1.5 cm of the yellow inked isthmus margin

Appearance of thyroid gland away from tumor: There is a scant amount of dark red/brown normal appearing thyroid tissue in the most inferior pole of the specimen near the isthmus. Adjacent to the isthmus margin is a 1.0 x 0.8 x 0.8 cm firm white/tan nodule.

[page 4 of 5]
Parathyroids: None identified

Tissue submitted for special investigations: Tumor is given to tissue procurement

Lymph nodes: Submitted separately

Digital photograph taken: No

Block Summary:

Inking: Anterior blue, posterior black and isthmus yellow

D1 - Perpendicular sections of superior margin
D2 - Nodule adjacent to isthmus
D3 - Tumor in relationship to yellow inked isthmus
D4 - Tumor at inferior pole in relationship to adjacent normal
D5-D10 - Representative sections of tumor to include relationship to blue inked anterior and black inked posterior margins
Tissue remains in formalin

Container E is additionally labeled "right modified neck dissection level 2, 3, 4" and it consists of an unoriented 9.5 x 8.0 x 3.5 cm aggregate of matted enlarged lymph node candidates. The largest lymph node candidate is 6 cm in greatest dimension.

Block Summary:

E1 - Six lymph node candidates
E2 - Five lymph node candidates
E3 - Five lymph node candidates
E4 - Three lymph node candidates
E5 - One lymph node candidate, bisected
E6 - One lymph node candidate, bisected
E7 - One lymph node candidate, bisected
E8 - Representative sections from one grossly positive lymph node candidate
E9 - Representative sections from one grossly positive lymph node candidate
E10 - Representative sections from one grossly positive lymph node candidate
E11 - Representative sections from one grossly positive lymph node candidate
E12 - Representative sections from one grossly positive lymph node candidate

[page 5 of 5]
Container F is additionally labeled "right neck level 2B" is a 4.3 x 2.5 x 1.4 cm aggregate of yellow/tan fibrofatty tissue is dissected for lymph node candidates. Lymph node candidates up to 1.4 cm in greatest dimension are identified.

Block Summary:

F1 - Six lymph node candidates

F2 - Three lymph node candidates

F3 - One lymph node candidate, bisected

F4 - One lymph node candidate, bisected

F5 - One lymph node candidate, (largest), sectioned

A small amount of fat remains in formalin

Critera	Yes	No
Discrepancy		
Primary Site Discrepancy		
Discrepancy		
Discrepancy History		
Discrepancy Primery Noted		
Qualification	QUALIFIED	D.SQUALIFIED
Reviewed	Date Reviewed: 9/21/12	

WMT

10/21/12

Source: NCI Genomic Data Commons file 26e57d34-4fa1-48cd-9bf5-e2f93d50ec9a (TCGA-DE-A4MD.ECDA6157-FC03-47FD-8070-C082DF08E75D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).